Somatic mutation profile of tumor specimen TARGET-10-PAPADT-09A (aliquot TARGET-10-PAPADT-09A-01D) from TARGET case TARGET-10-PAPADT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (575 days).
Specimen TARGET-10-PAPADT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9b2d48-e4da-4605-a8e6-c5668a8e549d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPADT-10A (Blood Derived Normal), aliquot TARGET-10-PAPADT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa5ddf1c-1390-4f57-91e1-c9c85441a50c

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/80 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RBM23 | c.532C>T p.R178W (on ENST00000359890 / NM_001077351.2; = p.R162W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs774365880, COSV57128716; called by muse, mutect2, varscan2
- TENM3 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs774602911, COSV101304641, COSV69306077; called by muse, mutect2, varscan2
- EGF | c.796A>G p.M266V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA5 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ABHD11 | c.876G>A p.P292= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs143792326; called by muse, mutect2, varscan2
- PAPPA2 | c.4893C>A p.I1631= | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as COSV62810035; called by muse, mutect2, varscan2
- AL353807.1 | n.238C>A | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- SBNO2 | c.*4G>T | 3'UTR (SNP) | VAF 2/8 reads (25%) | catalogued as rs759751371; called by muse, mutect2
